CCDI case PBCICU — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/55044c7f-2223-45b2-97b6-77896c54d9ac

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Atypical teratoid/rhabdoid tumor: ICD-O-3 morphology code: 9508/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 2.7 years (978 days).

Biospecimens (3 samples)
- Sample 0DTRE9: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DTREG: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DTREN: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
